Somatic mutation profile of tumor specimen TCGA-W5-AA2O-01A (aliquot TCGA-W5-AA2O-01A-11D-A417-09) from TCGA case TCGA-W5-AA2O, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 57.8 years (21,118 days).
Specimen TCGA-W5-AA2O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a750125-b3d0-4689-8117-bc2911d75f6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2O-10A (Blood Derived Normal), aliquot TCGA-W5-AA2O-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1aeef5e4-56e6-443e-81f8-e2ff8c98d190

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Nonsense Mutation 3, Splice Site 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 40/74 reads (54%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CA6 | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780990647; called by muse, mutect2, varscan2
- FBN3 | c.2569C>T p.R857W | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs780755016; called by muse, mutect2
- MUC16 | c.14486A>G p.N4829S | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.445); catalogued as COSV101199351; called by muse, mutect2, varscan2
- MVD | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs748943997; called by muse, mutect2, varscan2
- NYAP2 | c.1442C>A p.S481* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as rs759695162; called by muse, mutect2, varscan2
- PDCL | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV52343616; called by muse, mutect2, varscan2
- PXDNL | c.2836C>T p.R946* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as rs1432085650, COSV62478278, COSV62500583; called by muse, mutect2
- RREB1 | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58553862; called by muse, mutect2
- TMEM132D | c.755C>G p.T252R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV70620013; called by muse, mutect2, varscan2
- ACO2 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS20 | c.5111G>A p.C1704Y | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP11 | c.1057A>C p.S353R | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FAT1 | c.5564C>T p.P1855L | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT1 | c.1129-2A>C p.X377_splice | Splice Site (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- OR6C3 | c.191C>A p.S64Y | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- STON1-GTF2A1L | c.3101C>T p.S1034F | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TMPRSS11A | c.1138C>A p.L380M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.851); called by muse, mutect2
- VAV3 | c.1503-1G>T p.X501_splice | Splice Site (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- WNK1 | c.1352A>G p.E451G | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AKNA | c.3750G>A p.Q1250= | Silent (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.732G>A p.V244= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs748327244; called by muse, mutect2, varscan2
- NLRP5 | c.276C>T p.T92= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV66767006; called by muse, mutect2, varscan2
- SRFBP1 | c.1113A>T p.P371= | Silent (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- TMEM132D | c.756A>G p.T252= | Silent (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- FGFR2 | c.939+1192_939+1194dup | Intron (INS) | VAF 43/53 reads (81%) | called by mutect2, pindel, varscan2
- SNORD3B-1 | n.116C>T | RNA (SNP) | VAF 30/91 reads (33%) | catalogued as rs765986809; called by muse, varscan2
